Somatic mutation profile of tumor specimen TCGA-DJ-A3V9-01A (aliquot TCGA-DJ-A3V9-01A-11D-A23M-08) from TCGA case TCGA-DJ-A3V9, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 50.4 years (18,399 days).
Specimen TCGA-DJ-A3V9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c89162f-3acb-43a8-9aa5-9affc4bdd0d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A3V9-10A (Blood Derived Normal), aliquot TCGA-DJ-A3V9-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76658c03-d6a8-45e3-9a60-9d628adc755b

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- KALRN | c.4609G>A p.V1537M | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs1163436733, COSV99564048; called by muse, mutect2, varscan2
- LRRC28 | c.1089T>G p.F363L | Missense Mutation (SNP) | VAF 20/448 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV100113564; called by muse, mutect2
- RRP12 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV100213153; called by muse, mutect2, varscan2
- CAMSAP3 | c.678G>A p.V226= | Silent (SNP) | VAF 10/80 reads (13%) | catalogued as COSV99350605; called by muse, mutect2, varscan2
